Somatic mutation profile of tumor specimen TCGA-BL-A13J-01A (aliquot TCGA-BL-A13J-01A-11D-A271-08) from TCGA case TCGA-BL-A13J, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.5 years (23,927 days).
Specimen TCGA-BL-A13J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38b71f69-aebb-4c24-b1aa-ef9ea083da2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BL-A13J-10A (Blood Derived Normal), aliquot TCGA-BL-A13J-10A-01D-A271-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fccd171-4232-4936-bc14-df1bd34bb229

The open-access MAF lists 113 somatic variants for this specimen: 81 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 31, Nonsense Mutation 8, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs371898076, CM993620; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 17/23 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs371321397; called by muse, mutect2, varscan2
- ANK2 | c.11525G>A p.R3842Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs770954138, COSV100003250, COSV52157432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO4 | c.2554C>A p.P852T (on ENST00000392977 / NM_001286615.2; = p.P817T on NM_178826.4) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.062); catalogued as COSV54616305; called by muse, mutect2, varscan2
- AP1B1 | c.2204C>G p.S735* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100434874; called by muse, mutect2
- ARHGEF1 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs369443387; called by muse, mutect2, varscan2
- ARHGEF5 | c.2620G>A p.G874S | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs761935499, COSV50221605; called by muse, mutect2, varscan2
- BCAS3 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs766394914, COSV66771518; called by muse, mutect2, varscan2
- CARM1 | c.1775C>A p.S592Y | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); catalogued as COSV53405220; called by muse, mutect2, varscan2
- CDH22 | c.572T>A p.M191K | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV64839925; called by muse, mutect2, varscan2
- CENPE | c.2466C>G p.F822L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV54392225, COSV99477540; called by muse, mutect2, varscan2
- CNTNAP4 | c.2771G>A p.R924K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV56703997; called by muse, mutect2
- CPD | c.3145T>A p.C1049S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.999); catalogued as COSV56716919; called by muse, mutect2, varscan2
- CUBN | c.1618T>C p.S540P | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.856); catalogued as COSV64729121; called by muse, mutect2, varscan2
- DACH1 | c.2150A>T p.D717V (on ENST00000619232 / NM_001366712.1; = p.D463V on NM_004392.6) | Missense Mutation (SNP) | VAF 104/183 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); catalogued as COSV57522063; called by muse, mutect2, varscan2
- DNAJB11 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV54004008, COSV99408766; called by muse, mutect2, varscan2
- DSCAML1 | c.3830C>T p.P1277L (on ENST00000321322; = p.P1217L on NM_020693.4) | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.758); catalogued as COSV58404543; called by muse, mutect2, varscan2
- DYRK4 | c.731C>G p.A244G | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV50546606; called by muse, mutect2, varscan2
- EDC4 | c.858del p.K287Sfs*7 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as COSV62768312; called by mutect2, pindel, varscan2
- EIF2B1 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99434892; called by muse, mutect2, varscan2
- F8 | c.6383G>C p.G2128A | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64279510; called by muse, mutect2, varscan2
- FAM193A | c.1835C>T p.T612M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768646940, COSV61199558; called by muse, mutect2, varscan2
- FASTKD3 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV52947409; called by muse, mutect2, varscan2
- FAT4 | c.6682A>C p.T2228P | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV58712631; called by muse, mutect2, varscan2
- FERD3L | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51764680; called by muse, mutect2, varscan2
- FKBP5 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61884214; called by muse, mutect2, varscan2
- FLG | c.11259G>T p.E3753D | Missense Mutation (SNP) | VAF 108/803 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.968); catalogued as rs563905924, COSV64242850; called by muse, mutect2, varscan2
- FLRT2 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV58151488; called by muse, mutect2, varscan2
- GBP4 | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100864481; called by muse, mutect2, varscan2
- GTF3C3 | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99827094; called by muse, mutect2, varscan2
- H2BC18 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.338); catalogued as COSV100516198; called by muse, mutect2, varscan2
- HMCN1 | c.12346G>A p.G4116R | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs747104381, COSV54947534; called by muse, mutect2, varscan2
- HOXB4 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as COSV100203873; called by muse, mutect2, varscan2
- IGLV3-27 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 53/232 reads (23%) | catalogued as rs1356344578; called by muse, mutect2, varscan2
- IMP4 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV52091658, COSV52093015; called by muse, mutect2, varscan2
- ITSN1 | c.4655G>A p.R1552Q | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as rs1408360223, COSV67157162; called by muse, mutect2, varscan2
- LILRA2 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs555278253, COSV52198103, COSV99253816; called by muse, mutect2, varscan2
- LRGUK | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 23/111 reads (21%) | catalogued as COSV99604792; called by muse, mutect2, varscan2
- MACF1 | c.19616G>C p.R6539T (on ENST00000372915; = p.R4584T on NM_012090.5) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV57148634; called by muse, mutect2, varscan2
- MAGEE2 | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1405159038, COSV64898666; called by muse, mutect2, varscan2
- MRPL35 | c.376A>C p.K126Q | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV54491979, COSV54494418; called by muse, mutect2, varscan2
- NCF2 | c.1067T>A p.V356E | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62316956; called by muse, mutect2
- NUDT14 | c.82-1G>A p.X28_splice | Splice Site (SNP) | VAF 14/72 reads (19%) | catalogued as COSV59650867; called by muse, mutect2, varscan2
- NXPH2 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV55641935, COSV55647471; called by muse, mutect2
- NXPH2 | c.526A>T p.T176S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV55647488; called by muse, mutect2
- OR10T2 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs772691278, COSV57783296, COSV57784051; called by muse, mutect2
- OR2Z1 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.149); catalogued as rs781891021, COSV60691642; called by muse, mutect2, varscan2
- OR5B21 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.115); catalogued as COSV64482103, COSV64482343; called by muse, mutect2
- P3H1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs1440258565, COSV52532704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAK3 | c.1615C>A p.P539T (on ENST00000262836 / NM_001324328.2; = p.P524T on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53281539; called by muse, mutect2
- PDE1C | c.1564A>G p.R522G | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV58531640; called by muse, mutect2, varscan2
- PHKA1 | c.2148G>A p.M716I | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV59812647; called by muse, mutect2, varscan2
- PLEKHG5 | c.2689C>T p.R897C (on ENST00000400915 / NM_001042663.3; = p.R860C on NM_020631.6) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.732); catalogued as rs557256913, COSV61070038; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POP1 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs376126108, COSV62894386; called by muse, mutect2, varscan2
- PPFIA1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 217/477 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV54141651; called by muse, mutect2, varscan2
- RALGPS2 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61340340; called by muse, mutect2, varscan2
- RARA | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV54191093; called by muse, mutect2, varscan2
- RNASEL | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as COSV62378149; called by muse, mutect2, varscan2
- RYR3 | c.1280G>C p.R427P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs765542021, COSV101213715, COSV66794661; called by muse, mutect2, varscan2
- SCAPER | c.1867G>C p.V623L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV100239823; called by muse, mutect2
- SCN3A | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.176); catalogued as COSV51827121; called by muse, mutect2, varscan2
- SERPINB13 | c.84C>G p.F28L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV54031422, COSV99501058; called by muse, mutect2, varscan2
- SFRP4 | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs765640507, COSV52262265; called by muse, mutect2, varscan2
- SLC38A2 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV56746722; called by muse, mutect2, varscan2
- SLC7A3 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV53229756, COSV99979486; called by muse, mutect2, varscan2
- SLMAP | c.347-1G>A p.X116_splice | Splice Site (SNP) | VAF 27/44 reads (61%) | catalogued as COSV55854942; called by muse, mutect2, varscan2
- SPAG17 | c.1620G>C p.K540N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); catalogued as COSV60469139, COSV60470058; called by muse, mutect2, varscan2
- STAG2 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV54372654, COSV54374641; called by muse, mutect2, varscan2
- TIAM1 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as COSV54536097, COSV54578339; called by muse, mutect2, varscan2
- TRIM36 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.296); catalogued as COSV56693840; called by muse, mutect2
- UPB1 | c.618C>A p.N206K | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV58116397; called by muse, mutect2, varscan2
- USP43 | c.2869G>T p.E957* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99557129; called by muse, mutect2, varscan2
- YAE1 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV56233139, COSV56233976; called by muse, mutect2, varscan2
- ZIM3 | c.649C>G p.H217D | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs150862431, COSV54141873; called by muse, mutect2, varscan2
- ZNF516 | c.1714G>A p.G572S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV71587739; called by muse, mutect2, varscan2
- ZNF626 | c.557C>G p.S186* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as rs187292121, COSV74129630; called by muse, mutect2, varscan2
- ZNF644 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV61350774; called by muse, mutect2, varscan2
- ZNF668 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100336980; called by muse, mutect2, varscan2
- ZNF813 | c.883G>T p.G295* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | catalogued as COSV101125020; called by muse, mutect2, varscan2
- SPATA31A1 | c.3526dup p.S1176Ffs*13 | Frame Shift Ins (INS) | VAF 338/554 reads (61%) | called by mutect2, pindel, varscan2
- AFM | c.1227C>G p.L409= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV56922634; called by mutect2, varscan2
- AHNAK | c.12414G>C p.L4138= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as rs1487990488, COSV57234149; called by muse, mutect2, varscan2
- ALDOB | c.234C>T p.I78= | Silent (SNP) | VAF 91/148 reads (61%) | catalogued as COSV66398795; called by muse, mutect2, varscan2
- ANO6 | c.2106C>T p.D702= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs201874992, COSV57666426; called by muse, mutect2, varscan2
- ATP8B2 | c.3546G>T p.L1182= (on ENST00000672630; = p.L1149= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV63834297; called by muse, mutect2, varscan2
- C20orf96 | c.999C>G p.V333= (on ENST00000360321 / NM_153269.3; = p.V332= on NM_080571.1) | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV64404769; called by muse, mutect2, varscan2
- CD300LF | c.807C>T p.L269= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV56899523; called by muse, mutect2, varscan2
- CDH2 | c.369G>A p.L123= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV52298626; called by muse, mutect2, varscan2
- DLST | c.1350C>G p.L450= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV53168185; called by muse, mutect2, varscan2
- ELOVL7 | c.27G>A p.R9= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs547294540, COSV70918800; called by muse, mutect2, varscan2
- GRM8 | c.945A>T p.I315= | Silent (SNP) | VAF 43/143 reads (30%) | catalogued as COSV58876485; called by muse, mutect2, varscan2
- KCNU1 | c.3063A>T p.P1021= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV67760357; called by muse, mutect2, varscan2
- MAPKAPK3 | c.885C>A p.I295= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV63598716; called by muse, mutect2, varscan2
- MAPKAPK3 | c.1053C>T p.I351= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV63597883, COSV63598720; called by muse, mutect2, varscan2
- MCM3AP | c.4101G>A p.P1367= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs769437831, COSV52446463; called by muse, mutect2, varscan2
- MTTP | c.1791G>C p.L597= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs1315427167, COSV55510522; called by muse, mutect2, varscan2
- NLGN4X | c.1299G>A p.P433= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as rs761743135, COSV52039892; called by muse, mutect2, varscan2
- NLRP2 | c.631C>T p.L211= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV54761380; called by muse, mutect2, varscan2
- OR4C6 | c.897C>T p.L299= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV58606767; called by muse, mutect2, varscan2
- PCDHA1 | c.1356G>A p.A452= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs1324578987, COSV65377384; called by muse, mutect2, varscan2
- POPDC3 | c.249A>G p.V83= | Silent (SNP) | VAF 79/177 reads (45%) | catalogued as rs760385641, COSV54646633; called by muse, mutect2, varscan2
- SEC31A | c.1887C>T p.I629= (on ENST00000355196 / NM_001318120.1; = p.I590= on NM_016211.4) | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100022413; called by muse, mutect2, varscan2
- SLC38A2 | c.249G>C p.A83= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV56746715, COSV99874044; called by muse, mutect2, varscan2
- SVIL | c.4257C>T p.S1419= (on ENST00000355867 / NM_021738.3; = p.S993= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV63449070; called by muse, mutect2, varscan2
- TBXT | c.1131G>T p.R377= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV51619364; called by muse, mutect2, varscan2
- TELO2 | c.1344C>T p.D448= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as rs370665424; called by muse, mutect2, varscan2
- TGM2 | c.2028G>A p.V676= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100821802; called by muse, mutect2, varscan2
- TMEM163 | c.384C>T p.D128= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs754153578, COSV56106831; called by muse, mutect2, varscan2
- ZNF285 | c.1311C>T p.F437= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV58411280; called by muse, mutect2, varscan2
- ZNF555 | c.759G>A p.E253= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV62074227; called by muse, mutect2, varscan2
- ZNF831 | c.1881G>T p.T627= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV100926117, COSV64046034; called by muse, mutect2, varscan2
- BRWD1 | c.6571+146G>A | Intron (SNP) | VAF 49/404 reads (12%) | catalogued as rs749445173, COSV60903824; called by muse, mutect2, varscan2
